Somatic mutation profile of tumor specimen TCGA-HC-7078-01A (aliquot TCGA-HC-7078-01A-11D-2114-08) from TCGA case TCGA-HC-7078, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.5 years (25,402 days).
Specimen TCGA-HC-7078-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f976b8a5-342f-4e1e-acac-9b6c265b6f14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7078-10A (Blood Derived Normal), aliquot TCGA-HC-7078-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/082b4852-c399-4cc4-9f34-948100d299c8

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 23, Silent 5, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO10 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs1055034872, COSV52736113; called by muse, mutect2, varscan2
- CACNB1 | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60000189; called by muse, mutect2, varscan2
- CCDC74B | c.114C>G p.S38R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV60103638; called by muse, mutect2, varscan2
- CLTCL1 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780344135, COSV54238715; called by muse, mutect2
- CRACD | c.1771G>T p.V591F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51731125, COSV51731697; called by muse, mutect2, varscan2
- FYCO1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV56119401; called by muse, mutect2, varscan2
- GRIA1 | c.1970C>A p.T657K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53623579; called by muse, mutect2, varscan2
- HCN3 | c.1476G>T p.G492= | Splice Region (SNP) | VAF 63/201 reads (31%) | catalogued as COSV61362484; called by muse, mutect2, varscan2
- HOXD10 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs761017009, COSV50903594, COSV99983086; called by muse, mutect2, varscan2
- KANSL1 | c.2315T>G p.L772R | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV52273820; called by muse, mutect2, varscan2
- KCNJ4 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.759); catalogued as rs1213024759, COSV57856448, COSV57856522; called by muse, mutect2, varscan2
- OR1Q1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs544593447, COSV52917629; called by muse, mutect2
- OR5H6 | c.880T>C p.Y294H (on ENST00000642105; = p.Y278H on NM_001005479.2) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760236883, COSV67352074; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV59014807; called by muse, mutect2, varscan2
- POLR1B | c.3007C>G p.R1003G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54503621; called by muse, mutect2, varscan2
- RECQL5 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV58646166; called by muse, mutect2, varscan2
- SLC26A1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs377629899; called by muse, mutect2, varscan2
- SMAD2 | c.1297A>G p.S433G | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV50998636, COSV51052791; called by muse, mutect2, varscan2
- SPANXD | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV65152886; called by muse, mutect2, varscan2
- SPPL2B | c.1288G>C p.A430P | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66317386; called by muse, mutect2, varscan2
- SYNC | c.1355A>G p.Y452C | Missense Mutation (SNP) | VAF 154/383 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201938976, COSV65131259; called by muse, mutect2, varscan2
- TMEM145 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs933612732, COSV56627707; called by muse, mutect2, varscan2
- TNXB | c.9553G>A p.A3185T (on ENST00000647633; = p.A2938T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs780721675, COSV64488384; called by muse, mutect2, varscan2
- TXNRD1 | c.1882G>T p.V628L (on ENST00000525566 / NM_001093771.3; = p.V530L on NM_003330.4) | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61601491; called by muse, mutect2, varscan2
- ZNF91 | c.2380G>T p.G794* | Nonsense Mutation (SNP) | VAF 25/103 reads (24%) | catalogued as COSV56092588; called by muse, mutect2, varscan2
- ADCY4 | c.2628C>T p.F876= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs761390459, COSV60253945, COSV60257486; called by muse, mutect2, varscan2
- CD86 | c.801A>T p.L267= (on ENST00000330540 / NM_175862.5; = p.L261= on NM_006889.4) | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV52610147; called by muse, mutect2, varscan2
- CYFIP1 | c.1182G>A p.A394= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1470005321; called by muse, mutect2, varscan2
- EHD1 | c.1263G>A p.P421= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs756567196, COSV57736657; called by muse, mutect2
- LRG1 | c.708G>A p.P236= | Silent (SNP) | VAF 53/604 reads (9%) | catalogued as rs200554386, COSV56702742; called by muse, mutect2
